Somatic mutation profile of tumor specimen TCGA-NA-A4QX-01A (aliquot TCGA-NA-A4QX-01A-11D-A28R-08) from TCGA case TCGA-NA-A4QX, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 61.0 years (22,264 days).
Specimen TCGA-NA-A4QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe67a9be-5ba1-4e7a-8ad7-a6151b9057b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4QX-10A (Blood Derived Normal), aliquot TCGA-NA-A4QX-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75880bf1-1fc2-480a-8a45-7335f7d06c80

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, In Frame Del 2, Splice Region 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1343_1360del p.K448_N453del (on ENST00000521381 / NM_181523.3; = p.K178_N183del on NM_181504.4) | In Frame Del (DEL) | VAF 10/34 reads (29%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PPP2R1A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 133/172 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1555791268, COSV59042459, COSV59042650; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527_528insA p.C176* | Nonsense Mutation (INS) | VAF 19/36 reads (53%) | hotspot (GDC flag); catalogued as COSV52756284, COSV99037144, COSV99403879; called by mutect2, pindel, varscan2
- C2orf16 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs759896889, COSV68646865; called by muse, mutect2, varscan2
- CHD2 | c.3014G>T p.R1005I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV67713222; called by muse, mutect2, varscan2
- COL6A6 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV62024138; called by muse, mutect2, varscan2
- IGSF6 | c.405_407del p.G136del | In Frame Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs758754048; called by pindel, varscan2
- MFSD14B | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs201761715, COSV64702227; called by muse, mutect2, varscan2
- MINDY4 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs755220381; called by muse, mutect2, varscan2
- MRM2 | c.670A>G p.R224G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253078400; called by muse, mutect2, varscan2
- NCF1 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56877186, COSV99194294; called by muse, mutect2, varscan2
- OCM2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs778218099, COSV57535604; called by muse, mutect2, varscan2
- SCN10A | c.5819T>C p.I1940T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.023); catalogued as rs1559405198; called by muse, mutect2, varscan2
- SHROOM4 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs781806295; called by muse, mutect2, varscan2
- SLC1A3 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561288563, COSV54314019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A13 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as rs1183612224, COSV99674276; called by muse, mutect2, varscan2
- TAZ | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as CM115035; called by muse, mutect2, varscan2
- TIGIT | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs207463547, COSV67329174; called by muse, mutect2, varscan2
- CTBP2 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FUCA1 | c.768G>A p.K256= | Splice Region (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- HEATR5A | c.2818A>G p.I940V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.44324T>A p.I14775N (on ENST00000591111; = p.I7351N on NM_003319.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF211 | c.621_624del p.T208Gfs*33 (on ENST00000347302 / NM_198855.4; = p.T221Gfs*33 on NM_006385.5) | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- CKMT1B | c.1161C>T p.I387= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as rs771547579; called by muse, mutect2, varscan2
- DNASE1 | c.462C>T p.P154= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs372063579; called by muse, mutect2, varscan2
- IDH3G | c.939C>T p.T313= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs373358098; called by muse, mutect2, varscan2
- MYO15A | c.1485G>A p.V495= | Silent (SNP) | VAF 35/45 reads (78%) | called by muse, mutect2, varscan2
- NFATC3 | c.1641T>C p.D547= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2
- SCML2 | c.426G>T p.P142= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52620114; called by muse, mutect2, varscan2
- SLC10A3 | c.426G>A p.L142= | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- SYNJ1 | c.1407C>T p.S469= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs919941488, COSV59149569; called by muse, mutect2, varscan2
- TSEN2 | c.138C>T p.N46= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- ZC3H12B | c.1006T>C p.L336= | Silent (SNP) | VAF 69/159 reads (43%) | called by muse, mutect2, varscan2
- ZNF573 | c.747G>A p.Q249= (on ENST00000536220 / NM_001172692.1; = p.Q191= on NM_152360.3) | Silent (SNP) | VAF 42/448 reads (9%) | called by muse, mutect2
- SNORD116-17 | n.78G>A | RNA (SNP) | VAF 62/125 reads (50%) | catalogued as rs748586644; called by muse, mutect2, varscan2
